Somatic mutation profile of tumor specimen TCGA-D8-A3Z6-01A (aliquot TCGA-D8-A3Z6-01A-11D-A23C-09) from TCGA case TCGA-D8-A3Z6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 56.5 years (20,629 days).
Specimen TCGA-D8-A3Z6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e7070f0-923a-4fd6-8b51-0ef9f32b9e62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A3Z6-10A (Blood Derived Normal), aliquot TCGA-D8-A3Z6-10A-01D-A23C-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31185ac0-5816-4423-907e-523e402a8f7c

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Frame Shift Del 4, Silent 3, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.1363C>A p.L455M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV60906651; called by muse, mutect2, varscan2
- CDH1 | c.1291_1292del p.N431Qfs*14 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as COSV55734958; called by mutect2, pindel, varscan2
- DCDC1 | c.2987G>C p.R996T (on ENST00000597505 / NM_001367979.1; = p.R103T on NM_020869.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV60308111, COSV60312886; called by muse, mutect2, varscan2
- DENND2B | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1234202691, COSV58205029; called by muse, mutect2, varscan2
- H4C11 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.786); catalogued as rs1387545597, COSV61827191; called by muse, mutect2, varscan2
- LRRC14B | c.54C>A p.H18Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.287); catalogued as COSV52049634; called by muse, mutect2, varscan2
- NELFCD | c.216del p.F72Lfs*4 (on ENST00000602795; = p.F54Lfs*4 on NM_198976.4) | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as COSV59747143; called by mutect2, pindel
- PCDHA3 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as rs781988680, COSV100793703; called by muse, mutect2, varscan2
- PCDHGA8 | c.1572G>T p.Q524H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.182); catalogued as COSV53972805; called by muse, mutect2, varscan2
- PHLDB1 | c.1669T>C p.C557R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61879663; called by muse, mutect2, varscan2
- RASSF7 | c.941C>G p.P314R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV60347472; called by muse, mutect2, varscan2
- SAFB2 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV52652107; called by muse, mutect2, varscan2
- SCYL2 | c.1331A>G p.E444G | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV62569364; called by muse, mutect2, varscan2
- SEMA4C | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs955856957, COSV100561150; called by muse, mutect2
- TERT | c.2633C>A p.T878N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.178); catalogued as COSV57211192, COSV57222029; called by muse, mutect2, varscan2
- TSHZ1 | c.2602G>A p.D868N (on ENST00000580243 / NM_001308210.2; = p.D823N on NM_005786.6) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100433398, COSV59012126; called by muse, mutect2, varscan2
- TXNDC11 | c.1145T>G p.I382R (on ENST00000356957 / NM_001303447.2; = p.I355R on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV51600335; called by muse, mutect2
- YTHDF1 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1420752238, COSV64833301; called by muse, mutect2, varscan2
- F11R | c.143_145del p.L48del | In Frame Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.1138_1139del p.L380Kfs*4 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- TJP1 | c.1435_1455delinsTC p.I479Sfs*12 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by pindel, varscan2*
- GPAM | c.1392G>A p.L464= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV62081541; called by muse, mutect2, varscan2
- KLHL40 | c.1557C>T p.T519= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1314573843, COSV55135269; called by muse, mutect2, varscan2
- MED12 | c.2286G>A p.K762= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV61344368; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504814 A>T | 5'Flank (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
